Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A89Z, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A89Z-01A (Primary Tumor).

ID 6-3
Astrocytoma, grade III
Site Brain, supratentorial NOS
Brain NOS C71.9
9/11/24/13

Astrocytic tumor with increased proliferation.
IDH1 R132H mutation present

Diagnosis
Anaplastic astrocytoma WHO grade III

Untranslated original report
is housed at the BCR.

Source: NCI Genomic Data Commons file f6358853-7a9d-4397-b295-02c1e4f70513 (TCGA-S9-A89Z.DAAF016F-5C66-4E31-B57A-1F0857B181AD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).